Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0W2, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0W2-01A (Primary Tumor).

1CB-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium C54.1

hw 5/1/11

PATIENT HISTORY:

None provided. LMP: Not provided.
PRE-OP DIAGNOSIS: Endometrial cancer.
POST-OP DIAGNOSIS: Same.
PROCEDURE: Exploratory laparotomy, bilateral salpingo-oophorectomy, total abdominal hysterectomy.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 1.0 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 10 %, Posterior endomyometrium: 10 %

No invasion

DEPTH OF INVASION:**

No

ANGIOLYMPHATIC INVASION:

PRE-NEOPLASTIC CONDITIONS:

Complex endometrial hyperplasia with atypia

OTHER:

(epithelial, smooth muscle, others), Endometrial polyp, Leiomyoma

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 0

T STAGE, PATHOLOGIC:

pT1a

N STAGE, PATHOLOGIC:

pNX

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IA

Tumor Malignancy/History		X
Case L (circled):		

Source: NCI Genomic Data Commons file fcdc1381-2c74-455f-8926-db13e93a417b (TCGA-BG-A0W2.D9BDB0FB-9205-4E41-9D7D-B12C206A608E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).